Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8IK, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8IK-01A (Primary Tumor).

[page 1 of 4]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) ANTERIOR LYMPH NODE:
Fibroadipose tissue with vessels, no tumor present.
No lymph node present.
- (B) ANTERIOR APEX:
Prostatic tissue and skeletal muscle, no tumor present.
Inked surfaced free of prostatic glands.
- (C) RIGHT PELVIC LYMPH NODES:
Two lymph nodes, no tumor present.
- (D) LEFT PELVIC LYMPH NODES:
Four lymph nodes, no tumor present.
- (E) PROSTATE, SEMINAL VESICLES:
Supplemental report to follow.

CLF ICD-O-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
9/21/24/13

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) ANTERIOR LYMPH NODES – Received is a 3.0 x 2.5 x 1.5 cm aggregate of fibroadipose tissue. The specimen is dissected to reveal one possible lymph node measuring 1.0 x 0.6 x 0.2 cm. The specimen is submitted entirely.
SECTION CODE: A1, one possible lymph node; A2, remainder of the specimen submitted entirely.
- (B) ANTERIOR APEX – A piece of tan-red soft tissue (0.3 x 0.3 x 0.3 cm) with one edge inked by the surgeon to indicate margin. This edge is reinked blue and specimen submitted entirely on edge in B for frozen section diagnosis.
*FS/DX: FOCAL BENIGN GLANDS PRESENT, INKED MARGIN NEGATIVE.
- (C) RIGHT PELVIC LYMPH NODES - Yellow, fibrofatty fragment, 8.0 x 6.5 x 2.2 cm and containing two possible lymph nodes, 5.2 cm and 2.0 cm in diameter each. Lymph nodes are entirely submitted.
SECTION CODE: C1, one possible lymph node, intact; C2-C6, one possible lymph node, serially sectioned.
- (D) LEFT PELVIC LYMPH NODES - Yellow fibrofatty fragment, 7.5 x 7.5 x 1.0 cm, and containing multiple lymph nodes, ranging between 1.5 to 5.0 cm in diameter. The lymph nodes are entirely submitted.
SECTION CODE: D1-D4, one lymph node, serially sectioned; D5, two possible lymph nodes, intact; D6, one possible lymph node, bisected.
- (E) PROSTATE, SEMINAL VESICLES - Supplemental report to follow.

CLINICAL HISTORY

None given.

SNOMED CODES

[page 2 of 4]
Page: 2

Accession: [REDACTED]

Specimen Date/Time: [REDACTED]

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 3 of 4]
Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(E) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5). (SEE COMMENT)

TUMOR CONFINED TO THE PROSTATE.

MARGINS OF RESECTION FREE OF TUMOR. RECUTS PENDING.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH-GRADE.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

COMMENT

The prostate gland contains four separate foci of prostatic adenocarcinoma, two in the peripheral zone and two in the transition zone. The dominant tumor focus is located in the left lateral, left posterolateral and left posterior peripheral zone. This tumor focus measures 1.8 x 1.0 cm in the largest cross-sectional dimension and it is present in two cross sections and focally in the apex and base regions. The second tumor focus is located in the right posterolateral peripheral zone, exclusively in the base region. This tumor focus measures 0.8 x 0.4 cm in the largest cross-sectional dimension and it is present in three base sections. The third tumor focus is located in the right transition zone. This tumor focus measures 0.4 x 0.1 cm in the largest cross-sectional dimension and it is present in two cross sections and focally in the apical region. The fourth tumor focus is located in the left transition zone. This tumor focus measures 0.4 x 0.1 cm in the largest cross-sectional dimension and it is present in two cross sections and focally in the apical region. All tumor foci are confined to the prostate. The margins of resection are free of tumor.

GROSS DESCRIPTION

(E) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.5 x 3.5 x 3.8 cm, 34 grams, post fixation) has the usual shape. The soft tissue present along the left posterolateral aspect of the prostate appears slightly more abundant than along the right side. A tumor is palpated on the left base region. Serial cross sections after fixation demonstrate a firm area consistent with tumor in the left peripheral zone of the two cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: E1-E3, right seminal vesicle and segment of right vas deferens from the base towards the tip; E4-E6, left seminal vesicle and segment of left vas deferens from the base towards the tip; E7, prostatic base, right border; E8-E11, prostatic base, right posterior border; E12-E17, prostatic base, central portion; E18, prostatic base, left border; E19-E21, prostatic base, left posterior border; E22-E24, apex anterior; E25, E26, apex left; E27-E29, apex posterior; E30, E31, apex right; E32-E39, sections of the two cross sections of the prostate according to the specimen radiograph.

[page 4 of 4]
Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (E18, E20 and E21) denotes surfaces that do not represent the true margin of resection including anterior apex (inked by surgeon) and left base in an area which does not represent the true margin.

SNOMED CODES

Entire report and diagnosis completed by: [REDACTED]

-----END OF REPORT-----

Source: NCI Genomic Data Commons file af75aff7-6da6-45db-b0a3-2e2fe5033845 (TCGA-KK-A8IK.CBFE7CBE-890E-4749-9566-0CE41A93D69D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).